Somatic mutation profile of tumor specimen 0D8Y6N from CCDI case PBBICS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Gliosarcoma; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 17.4 years (6,373 days).
Specimen 0D8Y6N: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb44a16c-fcae-4113-aa9c-8fac2098b01e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D8Y6M (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38a7de15-8b59-444e-aa42-b548a5ef715f

The open-access MAF lists 60 somatic variants for this specimen: 45 protein-altering or splice-affecting, 4 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Intron 7, Silent 4, Splice Site 3, Nonsense Mutation 2, 3'Flank 1, 5'UTR 1, RNA 1, 3'UTR 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.672+1G>C p.X224_splice | Splice Site (SNP) | VAF 52/118 reads (44%) | hotspot (GDC flag); catalogued as CS071266, CS123101, COSV52670407, COSV52712339, COSV52751788; called by muse, mutect2, varscan2
- A2M | c.1697A>T p.N566I | Missense Mutation (SNP) | VAF 152/545 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59385351; called by muse, mutect2, varscan2
- ALPK1 | c.3288C>G p.N1096K | Missense Mutation (SNP) | VAF 115/374 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368356690; called by muse, mutect2, varscan2
- ANO4 | c.1792C>A p.L598I (on ENST00000392977 / NM_001286615.2; = p.L563I on NM_178826.4) | Missense Mutation (SNP) | VAF 143/492 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs267603264, COSV54614934; called by muse, mutect2, varscan2
- BFSP2 | c.808G>C p.D270H | Missense Mutation (SNP) | VAF 185/493 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.888); catalogued as COSV56591257; called by muse, mutect2, varscan2
- C12orf40 | c.821G>A p.G274E | Missense Mutation (SNP) | VAF 53/428 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as COSV61131200; called by muse, mutect2, varscan2
- CIC | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 135/209 reads (65%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs200659564; called by muse, mutect2, varscan2
- DICER1 | c.5113G>A p.E1705K | Missense Mutation (SNP) | VAF 77/304 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58615252, COSV58618257; called by muse, mutect2, varscan2
- IGSF22 | c.1258A>G p.K420E | Missense Mutation (SNP) | VAF 115/698 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as rs1224375169; called by muse, mutect2, varscan2
- MBOAT1 | c.336dup p.V113Cfs*46 | Frame Shift Ins (INS) | VAF 52/330 reads (16%) | catalogued as rs763568427; called by mutect2, varscan2
- NUAK1 | c.260G>T p.R87L | Missense Mutation (SNP) | VAF 60/365 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54605409, COSV99776415; called by muse, varscan2
- PHACTR2 | c.331C>G p.R111G | Missense Mutation (SNP) | VAF 186/399 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.131); catalogued as COSV99990917; called by muse, mutect2, varscan2
- RERG | c.88C>G p.R30G | Missense Mutation (SNP) | VAF 70/346 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV57000456; called by muse, mutect2, varscan2
- C14orf180 | c.80C>G p.A27G | Missense Mutation (SNP) | VAF 102/403 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- C9orf135 | c.122A>T p.K41I | Missense Mutation (SNP) | VAF 197/569 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CBWD5 | c.1019T>C p.L340P (on ENST00000382405 / NM_001330668.1; = p.L292P on NM_001024916.3) | Missense Mutation (SNP) | VAF 118/2380 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 23/696 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- CELSR3 | c.3559T>G p.F1187V | Missense Mutation (SNP) | VAF 85/196 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- COL6A5 | c.2504A>T p.N835I | Missense Mutation (SNP) | VAF 81/485 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- CRISP2 | c.184-1G>T p.X62_splice | Splice Site (SNP) | VAF 27/234 reads (12%) | called by muse, mutect2, varscan2
- CUBN | c.8726C>A p.A2909D | Missense Mutation (SNP) | VAF 30/656 reads (5%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.597); called by muse, mutect2
- DCAF8L2 | c.303C>G p.F101L | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DICER1 | c.3363C>G p.Y1121* | Nonsense Mutation (SNP) | VAF 187/495 reads (38%) | called by muse, mutect2, varscan2
- DZIP3 | c.1933T>A p.S645T | Missense Mutation (SNP) | VAF 45/326 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- FAM135B | c.3188T>C p.L1063P | Missense Mutation (SNP) | VAF 42/378 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- INPP4B | c.902T>A p.L301H | Missense Mutation (SNP) | VAF 93/607 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- KCNJ16 | c.513A>T p.K171N | Missense Mutation (SNP) | VAF 86/394 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF13B | c.585+1G>A p.X195_splice | Splice Site (SNP) | VAF 87/282 reads (31%) | called by muse, mutect2, varscan2
- LMOD2 | c.1102G>A p.G368R | Missense Mutation (SNP) | VAF 47/255 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MCOLN1 | c.1585G>A p.G529S | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MS4A14 | c.259G>T p.A87S | Missense Mutation (SNP) | VAF 99/332 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- MUC16 | c.7006A>C p.T2336P | Missense Mutation (SNP) | VAF 100/201 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- NOTCH1 | c.3060C>G p.H1020Q | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- OBSCN | c.10631T>G p.V3544G | Missense Mutation (SNP) | VAF 92/686 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2
- OR5V1 | c.164T>G p.L55R | Missense Mutation (SNP) | VAF 60/463 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDGFRB | c.1680_1697del p.R561_W566del | In Frame Del (DEL) | VAF 67/162 reads (41%) | called by mutect2, varscan2
- PRKCQ | c.1567T>A p.F523I | Missense Mutation (SNP) | VAF 180/341 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SH3TC2 | c.127T>A p.F43I | Missense Mutation (SNP) | VAF 127/715 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- SRPK2 | c.628A>T p.I210F | Missense Mutation (SNP) | VAF 82/519 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- STK35 | c.1510C>T p.Q504* | Nonsense Mutation (SNP) | VAF 116/243 reads (48%) | called by muse, mutect2, varscan2
- UBE2E3 | c.612A>C p.R204S | Missense Mutation (SNP) | VAF 128/338 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- UBE3A | c.103C>G p.R35G | Missense Mutation (SNP) | VAF 56/370 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- UGT2B7 | c.599A>T p.E200V | Missense Mutation (SNP) | VAF 72/543 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- USP3 | c.575C>G p.A192G | Missense Mutation (SNP) | VAF 84/530 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- VPS41 | c.1109T>A p.L370H | Missense Mutation (SNP) | VAF 239/641 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- OR56B1 | c.939G>A p.K313= | Silent (SNP) | VAF 231/646 reads (36%) | catalogued as COSV57723918; called by muse, mutect2, varscan2
- SLC5A1 | c.1125C>A p.P375= | Silent (SNP) | VAF 137/262 reads (52%) | called by muse, mutect2, varscan2
- TRIML2 | c.822A>G p.R274= | Silent (SNP) | VAF 73/549 reads (13%) | called by muse, mutect2, varscan2
- TRRAP | c.6189G>C p.T2063= (on ENST00000359863 / NM_001244580.1; = p.T2045= on NM_003496.3) | Silent (SNP) | VAF 92/473 reads (19%) | called by muse, mutect2, varscan2
- ANKRD44 | c.1100+10C>T | Intron (SNP) | VAF 140/445 reads (31%) | catalogued as rs375696827, COSV56550480; called by muse, mutect2, varscan2
- BSN | c.-80C>A | 5'UTR (SNP) | VAF 3/26 reads (12%) | called by muse, varscan2
- DDX41 | c.434+10T>C | Intron (SNP) | VAF 57/309 reads (18%) | called by mutect2, varscan2
- ERI2 | c.23+70G>T | Intron (SNP) | VAF 14/36 reads (39%) | called by mutect2, varscan2
- FBXL21P | n.1242T>C | RNA (SNP) | VAF 123/477 reads (26%) | called by muse, mutect2, varscan2
- KCNMB1 | c.306+80G>C | Intron (SNP) | VAF 15/52 reads (29%) | catalogued as rs748640750; called by muse, mutect2, varscan2
- MEGF10 | c.1693+1570del | Intron (DEL) | VAF 114/485 reads (24%) | called by mutect2, varscan2
- NBEAP2 | chr2:131751647 T>A | 3'Flank (SNP) | VAF 45/127 reads (35%) | called by muse, varscan2
- PCDHB16 | c.*74T>G | 3'UTR (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2, varscan2
- PLOD2 | c.1501-903G>C | Intron (SNP) | VAF 27/115 reads (23%) | called by muse, mutect2
- ZNF277 | c.801+32A>T | Intron (SNP) | VAF 11/313 reads (4%) | called by muse, mutect2
